Gene-level copy-number profile of tumor specimen TCGA-85-8049-01A from TCGA case TCGA-85-8049, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 57.5 years (20,995 days).
Specimen TCGA-85-8049-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.cf5d230f-1561-4bad-ab6a-bbb4b0b8b5e6.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8049-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/38c943c2-e154-41cb-b987-716d458f390e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 8; copy number 1: 239; copy number 2: 26,070; copy number 3: 16,597; copy number 4: 8,595; copy number 5: 4,714; copy number 6: 2,965; copy number 7: 24; copy number 8: 2; copy number 9: 350; copy number 11: 175; copy number 15: 32; copy number 17: 46.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8049-01A-11D-2243-01): tumor purity 0.2, ploidy 2.78, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 8,308 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:143,343,180–248,919,946, 2,604 genes, copy number 5–7 (broad region; genes not listed).
- chr3:119,780,484–185,825,042, 1,160 genes, copy number 5–15 (within-gene range 4–15) (broad region; genes not listed).
- chr6:48,701,491–55,579,197, 121 genes, copy number 5–8 (broad region; genes not listed).
- chr7:70,972–16,784,536, 279 genes, copy number 5 (broad region; genes not listed).
- chr7:45,859,994–159,233,377, 2,185 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr12:66,767–34,249,958, 850 genes, copy number 6 (broad region; genes not listed).
- chr17:29,625,938–29,930,276, 1 gene, copy number 5 (within-gene range 3–5): SSH2.
- chr17:29,716,279–34,174,964, 164 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr18:316,737–15,330,282, 366 genes, copy number 9–17 (within-gene range 3–17) (broad region; genes not listed).
- chr20:87,250–31,259,632, 573 genes, copy number 6 (broad region; genes not listed).
- chr21:23,352,929–23,490,724, 5 genes, copy number 7: D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1.

Autosomal genes at a single copy (total copy number 1): 239. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
